Surgical pathology report (de-identified scan), TCGA case TCGA-44-8119, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Christiana Healthcare, specimen TCGA-44-8119-01A (Primary Tumor).

[page 1 of 3]
[REDACTED]

Phone [REDACTED]

Final Surgical Pathology Report

Procedure: [REDACTED]

Diagnosis

A. Lung, right upper lobe with adjacent chest wall, en bloc resection:
Invasive poorly differentiated adenocarcinoma extending into the soft tissues of the chest wall.

The radial, vascular and bronchial margins of resection are free of tumor.

Apical emphysematous changes.

Benign pleural plaque.

4 hilar lymph nodes negative for metastatic carcinoma (0/4).

Nonnecrotizing granulomatous lymphadenitis; special stains for acid-fast and fungal organisms
are both negative.

B. Rib, third, medial margin:

Negative for malignancy.

C. Lymph nodes, part of 4R, resection:

Nonnecrotizing granulomatous lymphadenitis; negative for malignancy.

D. Lymph node, level X, resection:

Nonnecrotizing granulomatous lymphadenitis; negative for malignancy.

E. Lymph node, level XI, resection:

Nonnecrotizing granulomatous lymphadenitis; negative for malignancy.

F. Rib, fourth, medial margin:

Negative for malignancy.

G. Lymph node, 2R, resection:

Nonnecrotizing granulomatous lymphadenitis; negative for malignancy.

H. Lymph node, level IX, resection:

Nonnecrotizing granulomatous lymphadenitis; negative for malignancy.

I. Lymph node, level VII, resection:

Nonnecrotizing granulomatous lymphadenitis; negative for malignancy.

Microscopic Description:

Sections of the lung tumor reveals a poorly differentiated non-small cell carcinoma. The tumor does not have any well formed glands or areas of keratinization. Immunohistochemistry reveals positive staining for both CEA and TTF-1 with a negative result for CK 5/6 and P63. This pattern of staining is indicative of a adenocarcinoma. Results of the resection as summarized in the following template -

Histologic type: Adenocarcinoma

Histologic grade: Poorly differentiated

Primary tumor (pT): Tumor has extended from the lung through the chest wall into the soft tissue adjacent to ribs (pT3).

Margins of resection: Negative

Direct extension of tumor: Direct extension into the chest wall is present.

Venous (large vessel) invasion: Positive

Arterial (large vessel) invasion: Negative

[page 2 of 3]
[REDACTED]

Lymphatic (small vessel) invasion: Negative
Regional lymph nodes (pN): All of the hilar lymph nodes and sampled mediastinal lymph nodes are negative for metastatic carcinoma (pN0).
Distant metastasis (pM): pMx
Other findings: All the lymph nodes containing non-necrotizing granulomatous lymphadenitis. Special stains for acid-fast and fungal organisms are both negative.

Specimen

- A. Right upper lobe with chest wall
- B. 3rd rib margin medial
- C. Part of 4R
- D. level X nodes
- E. Level XI
- F. 4th rib medial margin
- G. 2R
- H. Level 9
- I. Level 7

Clinical Information

Lung mass

Intraoperative Consultation

[REDACTED] lobe - Poorly differentiated non-small carcinoma.
[REDACTED]
[REDACTED]

Gross Description

A. Received fresh labeled "right upper lobe with chest wall" is a 308 g, 18.0 x 11.0 x 4.5 cm lobectomy specimen with attached 1.5 cm in length, 1.5 x 1.5 cm in diameter bronchial stump. Several soft gray-black perihilar lymph nodes measuring up to 2.4 cm are recovered. A 19 cm staple line traverses the pleura (subsequently removed). Three ribs spanning an area of 9.8 x 5.8 cm are present along one aspect. The pleura is smooth to scabrous tan red with a subjacent induration adjacent to the adherent ribs. The pleura overlying the induration is inked orange. The external surface of the ribs is inked blue. On sectioning, there is a 5.5 x 4.7 x 3.5 cm rubbery tan-white to gray-black tumor mass subjacent to the adherent ribs. The tumor appears to extend into the intercostal muscles and to within 0.1 cm of the inked pleural surface. A portion of tumor and a portion of normal parenchyma are submitted for tissue procurement as requested. The remaining parenchyma is spongy form tan-red without additional mass lesion. Diffuse crepitation is present in the vicinity of the tumor mass. In addition, a rubbery 1.4 cm greatest dimension tan-white nodule is noted within the adherent pleura. [REDACTED]

Summary: 1 - bronchial margin, 2 - vascular margins, 3 and 4 - tumor to inked pleural surface, 5 and 6 - tumor to intercostal muscle, 7 and 8 - random tumor, 9 - random parenchyma, 10 - bisected pleural nodule, early 11 - 4 hilar lymph nodes, 12 and 13 - bisected largest hilar lymph node, 14 through 18 - tumor to rib following fixation and decalcification.
[REDACTED]

B. Received fresh labeled "3rd rib margin medial" is an irregular, 1.9 x 1.4 x 1.0 cm portion of focally fragmented hard tan-white bone with a scant amount of associated soft tissue. The specimen is inked, sectioned, and entirely submitted in one block following fixation and decalcification.

C. Received fresh labeled "part of 4R" is slightly fragmented 0.6 cm greatest dimension soft tan-gray tissue. [REDACTED]

D. Received fresh labeled "level X nodes" are 4 ft tan-gray tissues ranging from 0.4-0.8 cm in greatest dimension. [REDACTED]

[page 3 of 3]
E. Received fresh labeled "level XI" is a 0.7 x 0.5 x 0.4 cm soft tan-gray tissue which is bisected and entirely submitted in one block.

F. Received fresh labeled "4th rib medial margin" is an irregular, slightly fragmented, 1.5 x 1.3 x 0.5 cm hard tan-white portion of bone. The specimen is inked, sectioned, and entirely submitted in one block following fixation and decalcification.

G. Received fresh labeled "2R" are 3 soft tan-gray tissues ranging from 0.3-1.2 cm in greatest dimension.
Summary: 1 - 2 tissues, 2 - bisected large tissue

H. Received fresh labeled "level IX" is an irregular 1.3 x 0.3 x 0.2 cm soft tan-gray tissue which is submitted in toto in one block.

I. Received fresh labeled "level VII" are 2 soft tan-gray tissues averaging 1.4 cm in greatest dimension. The specimens are bisected and entirely submitted independently in 2 blocks.

Source: NCI Genomic Data Commons file 9d7b49f6-03bc-4086-9747-744de32157fc (TCGA-44-8119.C40EA4C8-8CBE-4A44-96D4-AE524A916449.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).